Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A0GH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A0GH-01A (Primary Tumor).

[page 1 of 4]
Adenocarcinoma,
Endometrioid, NOS

8380/3

lw
11/22/10

ne 15:58

Site: endometrium c54.1

PATH #:

A/S:

Rec:

Col:

Location:
Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

=====

- DIAGNOSIS:
1. UTERUS WITH BILATERAL TUBES AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGOOPHORECTOMY:
- Adenocarcinoma of endometrium (Endometrioid type)
- Focal clear cell features
- Histologic FIGO grade 2-3
- Nuclear grade 2
- The tumor invades less than half of myometrium
- The maximal thickness of myometrial invasion is 5 mm
- The thickness of the myometrium in the area of maximal tumor invasion is 15 mm
- No endocervical invasion is identified
- Small focus suspicious for angiolymphatic invasion (section C)
- The remaining endometrium shows atrophy
- Myometrium shows leiomyoma, calcified and focal adenomyosis
- Fibroma, minute, left ovary
- Inclusion cortical cysts, right ovary
- Involutional changes, bilateral ovaries
- Unremarkable fallopian tubes
- 2-8. LYMPH NODES: RIGHT OBTURATOR, RIGHT PELVIC, RIGHT OBTURATOR, RIGHT PELVIC, LEFT PELVIC, LEFT OBTURATOR, LEFT PERIAORTIC:
- Negative for metastatic carcinoma
- Benign lymph nodes (a total of eighteen nodes), 0/18
- 9.10. OMENTUM #1 AND #2:
- Benign lobulated adipose omental tissue
11. APPENDIX, APPENDECTOMY:
- Benign appendix with fibrous luminal obliteration

Report E-mailed to Dr.

=====

HISTORY: Endometrial cancer

Laboratory Medicine

Page: 2

MICROSCOPIC:

See Diagnosis.

GROSS:

1: UTERUS BILATERAL TUBES BILATERAL OVARIES
Labeled with the patient's name, designated "uterus bilateral tubes and ovaries", and received fresh for an intraoperative frozen section diagnosis and subsequently submitted in formalin. The uterus with attached cervix and bilateral adnexa weighs 92 grams. The uterus measures 7.5 cm from fundus to cervix 0.5 cm from cornu to cornu and 2.7 cm from 2.7 cm from anterior/posterior, and is

[page 2 of 4]
oriented by the relationship of the peritoneal reflections. The serosal surface of the uterus posterior and anteriorly shows several bosselations due to the presence of subserosal leiomyomas. The remainder of the serosal surface is pink-tan and smooth. The uterus is incised on both sides. The endometrial cavity is 0.3 cm long and 2.3 cm in width. The posterior endometrium shows tan polypoid friable tumor replacing the endometrium. Cut sections of the posterior endomyometrium shows tumor invading into the less than half of the myometrium. The anterior myometrium appears grossly uninvolved by the tumor. The endometrium measures 0.5 cm in thickness. The myometrium measures 1.5 cm. Cervix measures 2.5 cm in length and 2.0 cm in width. The external os is slit-shaped and measures 0.7 cm. Within the uterus there are a total of three leiomyomas two are subserosal and one is intramural. Cut sections of the leiomyomas are well circumscribed has a white solid whorling surface. The transition zone and the endocervical canal are unremarkable. The right fallopian tube measures 4.5 cm in length and 0.5 cm in average diameter the fimbria are lush and velvety. On cut sections the tube is unremarkable. The right yellow cerebriiform ovary measures 3.0 x 1.5 x 0.6 cm. On cut section the ovary is unremarkable. The left fallopian tube measures 6.0 cm in length and 0.5 cm in average diameter. The fimbria are lush and velvety. On cut section the tube is unremarkable. The left yellow cerebriiform ovary measures 2.0 x 1.3 x 0.4 cm. On cut section the ovary is unremarkable. Representative sections.

- A. Posterior cervix - 1
- B. Posterior lower uterine segment - 1
- C-E. Representative sections of posterior endomyometrium
- F. Remainder of the posterior endomyometrium
- G. Anterior cervix -1
- H,I. Endomyometrium entire cross section
- J. Representative section of anterior endomyometrium
- K. Ovary and fallopian tube - 3
- L. Left ovary and fallopian tube -3
- X. Representative sections of leiomyoma
- Y. Representative section of calcified leiomyoma after brief decalcification - 2

2: OBTURATOR LYMPH NODE RIGHT

Labeled with the patient's name, designated "obturator lymph node", is received fresh from the operating room for an intraoperative frozen section diagnosis and subsequently submitted in formalin. The lymph node measures 0.5 x 1.0 x 0.3 cm and is entirely embedded for frozen section 1. The fat was not embedded for frozen section. Entirely submitted.

M. Frozen section #1 control

(continued on next page)□

boratory Medicine

Page: 3

3: RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, designated "right pelvic lymph node", and received in formalin are multiple yellow-brown irregular moderately firm fragments of tissue ranging from 0.6 to 2.5 cm. The aggregate measurement is 3.0 x 2.5 x 0.5 cm. Entirely submitted.

O. Multiple

4: RIGHT OBTURATOR LYMPH NODE

Labeled with the patient's name, designated "right obturator lymph node", and received in formalin and consists of a yellow-brown irregular moderately firm piece of tissue measuring 1.5 x 0.4 x 0.2 cm. Entirely submitted.

[page 3 of 4]
P. 1

5: RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, designated "right periaortic lymph node", and received in formalin and consists of a yellow-brown irregular moderately firm tissue measuring 1.4 x 0.6 x 0.3 cm. Entirely submitted.

Q. 1

6: LEFT PELVIC LYMPH NODE

Labeled with the patient's name, designated "left pelvic lymph node", and received in formalin is multiple brown fragments of possible lymph node. The fragments of tissue range from 1.5 to 2.0 cm and are with an aggregate measurement of 2.5 x 2.4 x 0.5 cm. Entirely submitted.

R. Multiple

7: LEFT OBTURATOR LYMPH NODE

Labeled with the patient's name, designated "left obturator lymph node", and received in formalin and consists of yellow-brown fragments of adipose tissue and lymph node. The specimen measures 2.0 x 1.5 x 1.0 cm. Entirely submitted.

S. Multiple

8: LEFT PERI AORTIC LYMPH NODE

Labeled with the patient's name, designated "left periaortic lymph node", and received in formalin and consists of a yellow-tan irregular moderately firm tissue measuring 2.0 x 0.6 x 0.5 cm. Entirely submitted.

T. 1

9: OMENTUM 1

Labeled with the patient's name, designated "omentum #1" and received in formalin and consists of yellow-brown segment of omentum measuring 9.0 x 2.5 x 1.0 cm. No mass or nodules are seen. Sections reveals yellow lobulated unremarkable adipose tissue. Representative sections.

(continued on next page)

aboratory Medicine

Page: 4

10: OMENTUM 2

Labeled with the patient's name, designated "omentum #2", and received in formalin and consists of a yellow-brown segment of omentum measuring 15.0 x 3.0 x 0.7 cm. The specimen is serially sectioned and no masses of nodules are seen. Representative sections.

V. 2

11: APPENDIX

Labeled with the patient's name, designated "appendix", and received in formalin and consists of a pink-tan appendix with appendiceal fat measuring 6.0 cm in length and 0.4 cm in average diameter. The attached adipose tissue is unremarkable. The surgical margin is inked blue. Cut sections reveals obliterated lumen. Representative sections.

W. Longitudinal, cross section and surgical margin of appendix

[page 4 of 4]
Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

Endometrial adenocarcinoma (diagnosis on biopsy)

- Polypoid, friable, sessile mass invading into the myometrium (less than 1/2 of myometrial thickness)

Calcified fibroid.

Frozen section (specimen #2 right obturator lymph node):

- Negative for tumor. Benign lymph node.

OPERATIVE CONSULT (FROZEN):

Special Studies: Frozen Section

SNOMED Code:

See Also:

DATE

Pathologist, M.D.

I, M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.
Date Finalled

Source: NCI Genomic Data Commons file 690d40e6-bace-45e6-9107-db13048f7c41 (TCGA-A5-A0GH.8E29A939-5581-4176-B19E-14076F17726B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).